Gene-level copy-number profile of tumor specimen C3L-06421-02 from CPTAC case C3L-06421, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 52.0 years (18,981 days).
Specimen C3L-06421-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Antrum; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 0f55794d-a966-4772-8b5e-a0c67bd5a51c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-06421-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,717 have no estimate.
https://portal.gdc.cancer.gov/files/417b2ef1-964e-460e-b162-e30283733a8f

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 285; copy number 1: 364; copy number 2: 6,313; copy number 3: 21,453; copy number 4: 7,662; copy number 5: 14,412; copy number 6: 2,347; copy number 7: 2,394; copy number 8: 1,185; copy number 9: 359; copy number 10: 845; copy number 11: 771; copy number 12: 348; copy number 13: 6; copy number 16: 5; copy number 18: 33; copy number 24: 7; copy number 26: 4; copy number 28: 56; copy number 29: 12; copy number 30: 4; copy number 35: 29; copy number 51: 12.

Homozygous deletions (total copy number 0; autosomes only): 71 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:59,747,277–61,251,459, 2 genes (within-gene range 0–3): FHIT, AC093418.1.
- chr3:60,690,225–60,856,605, 4 genes: PPIAP70, AC104164.1, PPIAP71, U3.
- chr4:90,838,903–91,112,790, 2 genes (within-gene range 0–2): TMSB4XP8, AC004054.1.
- chr9:21,058,771–22,128,103, 53 genes (within-gene range 0–2): IFNNP1, IFNB1, IFNWP4, AL390882.1, IFNW1, Y_RNA, IFNA21, IFNWP15, IFNA4, IFNWP9, IFNA7, IFNA10, IFNWP18, IFNA16, IFNA17, IFNWP5, IFNA14, IFNA22P, IFNA5, IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.
- chr16:78,355,529–78,506,568, 2 genes (within-gene range 0–3): LSM3P5, AC046158.1.
- chr16:78,825,281–78,873,505, 2 genes (within-gene range 0–3): RPS3P7, AC136603.1.
- chr17:18,426,861–18,442,895, 2 genes: KRT17P2, KRT16P1.
- chr17:18,497,095–18,551,705, 4 genes (within-gene range 0–5): NOS2P2, FAM106A, USP32P2, SRP68P2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 6,070 genes in 29 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:56,145,721–58,546,734, 23 genes, copy number 7 (within-gene range 4–7): AL353681.1, AC119674.1, AC119674.2, RPSAP20, LINC01767, PLPP3, RPL21P23, RPL23AP85, AC099789.1, PRKAA2, FYB2, AL360295.1, C8A, C8B, AL161740.1, DAB1, AL390243.1, RPS20P5, DAB1-AS1, HNRNPA1P6, RPS26P15, AL445193.2, AL445193.1.
- chr1:149,754,301–150,780,644, 56 genes, copy number 8: AC243772.1, FCGR1A, H2BC18, AC243772.2, H3C13, H4C14, H3C14, H2AC18, H2BC19P, H2BC20P, H2AC19, H3C15, H4C15, AC239868.1, H2BC21, H2AC20, H2AC21, BOLA1, SV2A, SF3B4, MTMR11, OTUD7B, AC244033.2, AC244033.1, VPS45, PLEKHO1, RN7SL480P, ANP32E, RNU2-17P, AC242988.1, CA14, APH1A, C1orf54, CIART, MRPS21, PRPF3, RPRD2, TARS2, MIR6878, ECM1, FALEC, ADAMTSL4-AS2, ADAMTSL4, MIR4257, ADAMTSL4-AS1, MCL1, RN7SL473P, RN7SL600P, AL356356.1, ENSA, U4, GOLPH3L, HORMAD1, RNU6-1042P, CTSS, AL356292.1.
- chr1:248,548,756–248,937,043, 25 genes, copy number 7–13: AC098483.1, OR2AS1P, OR2T29, OR2T34, OR2T10, Y_RNA, AC098483.2, OR2T11, OR2T35, OR2T27, CR589904.2, OR14I1, LYPD9P, CR589904.1, AHCYP8, LYPD8, DPY19L4P1, SH3BP5L, MIR3124, ZNF672, ZNF692, AL672291.1, PGBD2, RNU6-1205P, RPL23AP25.
- chr2:41,819,747–49,419,013, 151 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr2:57,429,548–62,464,070, 80 genes, copy number 7–9 (broad region; genes not listed).
- chr4:37,241,910–38,572,022, 21 genes, copy number 7–8: MIR4801, NWD2, C4orf19, AC022463.1, AC027607.1, RELL1, Y_RNA, AC108022.1, PGM2, AC021106.2, AC021106.1, TBC1D1, PTTG2, PSME2P4, MRPS33P2, AC098680.1, LINC02513, AC024023.1, LINC01258, LINC01259, LINC02278.
- chr4:60,750,575–61,153,962, 4 genes, copy number 7: LINC02496, AC105420.1, MIR548AG1, LINC02271.
- chr4:63,465,511–63,529,761, 1 gene, copy number 8: AC093730.1.
- chr6:39,792,298–48,214,794, 204 genes, copy number 9–35 (broad region; genes not listed).
- chr7:37,032–89,754,726, 1,536 genes, copy number 7–11 (broad region; genes not listed).
- chr7:98,106,862–109,999,624, 310 genes, copy number 9 (broad region; genes not listed).
- chr8:8,059,572–15,238,431, 183 genes, copy number 7 (broad region; genes not listed).
- chr8:48,913,916–101,224,573, 791 genes, copy number 7–12 (broad region; genes not listed).
- chr8:102,688,317–109,121,565, 83 genes, copy number 7–11 (broad region; genes not listed).
- chr8:109,362,461–110,105,964, 10 genes, copy number 10: PKHD1L1, MAPK6P5, EBAG9, SYBU, AC079061.1, AC023245.2, AC023245.1, KCNV1, AC027451.1, RPSAP48.
- chr8:117,265,272–125,367,120, 126 genes, copy number 11–12 (broad region; genes not listed).
- chr8:127,289,817–128,564,679, 20 genes, copy number 9–11: CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, LINC00824.
- chr9:60,914,407–61,642,494, 15 genes, copy number 12–16: SPATA31A5, AL590491.1, FAM74A6, AL590491.2, AL590491.3, SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3, FAM242D, Y_RNA.
- chr9:79,391,304–79,567,802, 2 genes, copy number 7: CHCHD2P9, LNCARSR.
- chr11:49,817,778–50,422,316, 29 genes, copy number 8: AC130364.1, AC130364.2, TRIM51FP, AP006587.5, AP006587.6, AP006587.4, AP006587.3, TRIM51DP, AP006587.1, AP006587.2, OR4A1P, OR4A49P, OR4A18P, OR4A19P, OR4R3P, OR4C13, OR4C12, OR4C45, OR4C49P, GTF2IP11, AC109635.3, AC109635.6, PHKG1P3, AC109635.4, AC109635.2, AC109635.1, LINC02750, AC024405.2, AC024405.1.
- chr13:18,467,172–94,408,020, 1,029 genes, copy number 7 (within-gene range 1–7) (broad region; genes not listed).
- chr13:94,154,193–110,971,603, 222 genes, copy number 7 (broad region; genes not listed).
- chr13:113,977,783–114,337,626, 9 genes, copy number 7: RASA3, RASA3-IT1, CDC16, MIR548AR, MIR4502, UPF3A, CLCP2, CHAMP1, LINC01054.
- chr17:39,401,793–40,501,623, 55 genes, copy number 7–51 (within-gene range 5–51): AC005288.1, MED1, CDK12, RNU6-233P, NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7, IKZF3, KRT8P34, AC090844.1, ZPBP2, GSDMB, ORMDL3, AC090844.2, LRRC3C, GSDMA, PSMD3, AC090844.3, CSF3, MED24, MIR6884, SNORD124, THRA, NR1D1, AC068669.1, MSL1, CASC3, MIR6866, RAPGEFL1, MIR6867, WIPF2, CDC6, RARA, AC080112.4, RARA-AS1, AC080112.3, GJD3, AC080112.1, PPIAP54, RNA5SP441, AC080112.2, TOP2A, Y_RNA, RPL23AP75, IGFBP4, AC018629.1, TNS4.
- chr18:20,946,906–23,956,222, 63 genes, copy number 7 (within-gene range 3–7) (broad region; genes not listed).
- chr20:87,250–7,633,851, 204 genes, copy number 8 (broad region; genes not listed).
- chr20:16,177,933–26,251,546, 236 genes, copy number 7 (broad region; genes not listed).
- chr20:40,121,041–64,327,972, 574 genes, copy number 7–8 (broad region; genes not listed).
- chr21:10,612,455–13,120,807, 8 genes, copy number 8: SLC25A15P4, AF254982.1, IGHV1OR21-1, AP001464.1, ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1.

Autosomal genes at a single copy (total copy number 1): 64. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
